MP2PRT case MP2PRT-PATFCN — Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia (MP2PRT-ALL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acute Lymphoblastic Leukemia; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/aefe3ec6-aaf1-4dad-9b74-dccfa6717e66

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 20 years; Year of birth: 1989.

Diagnoses (1)
1. Common precursor B ALL: ICD-O-3 morphology code: 9836/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 20.7 years (7,549 days); Year of diagnosis: 2010; Days to last follow up: 1,880 days (5.1 years).
   Treatment given: Initial disease status: Initial Diagnosis; Regimen or line of therapy: (PC)  4 weeks Prednisone during Induction, Capizzi Methotrexate during Interim Maintenance I; Days to treatment start: 1 day; Days to treatment end: 856 days (2.3 years); Number of cycles: 5; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Treatment anatomic sites: Body, total.

Follow-up (1 entry)
- Days to follow up: 1,880 days (5.1 years); Disease response: Complete Response; Progression or recurrence: No; Days progression-free: 1,880 days (5.1 years).

Molecular and laboratory tests
- ABL1 (FISH): Negative.
- BCR (FISH): Negative.
- CRLF2 (Cytogenetics, NOS): Negative.
- ETV6 (FISH): Negative.
- KMT2A (FISH): Negative.
- RUNX1 (FISH): Negative.

Other clinical attributes
- Weight: 60.3 kg; Height: 159.1 cm; BMI: 23.82193048; Body surface area: 68.92135632.

Biospecimens (2 samples)
- Sample MP2PRT-PATFCN-NB1-A: Sample type: Blood Derived Cancer - Peripheral Blood, Post-treatment; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
- Sample MP2PRT-PATFCN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
